Gene-level copy-number profile of tumor specimen C3N-03425-05 from CPTAC case C3N-03425, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 64.5 years (23,574 days).
Specimen C3N-03425-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a710fba-a9dc-47be-aa49-46a2b700fc9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03425-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/ed7de2d8-a2eb-4fbc-a8ea-fba7718f5939

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 9,970; copy number 2: 33,460; copy number 3: 13,032; copy number 4: 1,640; copy number 5: 231; copy number 6: 7; copy number 8: 1; copy number 25: 9; copy number 47: 2; copy number 65: 7.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes (within-gene range 0–3): Y_RNA, RNU6-904P, RPS16P3.
- chr2:212,911,003–212,926,336, 3 genes (within-gene range 0–1): AC108066.1, MIR4776-1, MIR4776-2.
- chr2:212,999,691–213,284,205, 5 genes (within-gene range 0–1): IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr7:63,044,827–63,060,084, 2 genes: AC069285.2, AC069285.3.
- chr8:12,095,176–12,115,516, 2 genes: DEFB108D, ZNF705D.
- chr8:12,393,209–12,436,343, 5 genes: DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr9:30,388,935–31,645,160, 15 genes: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:63,728,877–63,744,910, 2 genes: AL772155.1, AL772155.2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 257 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr7:54,185,071–56,955,864, 86 genes, copy number 5–65 (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr14:18,333,726–18,637,421, 14 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr14:32,879,246–43,300,595, 142 genes, copy number 5 (broad region; genes not listed).
- chr14:66,111,557–67,181,803, 7 genes, copy number 5 (within-gene range 2–5): LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196, GPHN, AL133241.1.

Autosomal genes at a single copy (total copy number 1): 9,970. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
